Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6626, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6626-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. RIGHT COLON, TERMINAL ILEUM

DIAGNOSIS:

- A. RIGHT COLON, TERMINAL ILEUM, RIGHT HEMICOLECTOMY:
- INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA OF THE COLON, WITH INVASION INTO SUBSEROUS ADIPOSE TISSUE (4.2 X 3 X 0.7 CM).
- ALL SURGICAL MARGINS OF EXCISION, NEGATIVE FOR NEOPLASM.
- SEPARATE TUBULOVILLOUS ADENOMA, ADJACENT TO THE APPENDICEAL ORIFICE.
- APPENDIX WITH FIBROUS OBLITERATION OF THE DISTAL PORTION.
- PORTION OF TERMINAL ILEUM WITH NO SIGNIFICANT PATHOLOGIC CHANGES.
- SIXTEEN MESENTERIC LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/16).
- SEE TEMPLATE.

COLORECTAL CANCER TEMPLATE

Specimen Type:	Right hemicolectomy
Tumor Site:	Right (ascending) colon
Tumor Configuration:	Ulceration
Tumor Size:	4.2 x 3 x 0.6 cm
Histologic Type:	Adenocarcinoma
Histologic Grade:	G2: Moderately differentiated
Extent of Invasion:	Subserosa
Margins:	Margins uninvolved by invasive carcinoma (proximal, distal, radial)
Venous/Lymphatic Invasion:	Absent
Perineural Invasion:	Absent
Additional Pathologic Findings:	Adenoma
Extent of Resection:	R0: Complete resection with grossly and microscopically negative margins
Lymph Nodes:	Negative (0/16)
Implants:	Absent
Pathologic Stage:	pT3a N0 Mx

SPECIMEN(S):

A. RIGHT COLON, TERMINAL ILEUM

CLINICAL HISTORY:

Not given

GROSS DESCRIPTION:

A. RIGHT COLON, TERMINAL ILEUM

Received fresh for tissue procurement is a segment of terminal ileum with attached right colon. The terminal ileum is 4 cm in length and 4 cm in circumference and is grossly unremarkable. A segment of the right colon is 25 cm in length and 9.5 cm in maximum circumference. The serosal surface is tan-pink, smooth and grossly unremarkable. The attached appendix is 7 cm in length and 0.4 cm in diameter and shows unremarkable external and cut surfaces. The specimen is opened and shows a 4.2 x 3 x 0.6 cm tumor mass with central ulceration located at the mid portion of the right colon at 8 cm from the closest (distal margin) and 12.5 cm from the ileo-cecal valve. This lesion involves the portion of the colon which is not covered with serosa. It invades through the muscularis into the subserosa. A second polypoid lesion is identified in the area corresponding to the base of the appendix. This lesion measures 2.5 x 2.3 x 0.7 cm. Sectioning shows the lesion to be confined to the mucosa without definite evidence of invasion. The remainder of the colon shows an unremarkable tan pink mucosa.

Throughout the pericolic adipose tissue, multiple presumptive lymph nodes are identified ranging between 0.3 and 0.6 cm in greatest dimension. All the lymph nodes and representative sections of the specimen are submitted as follows:

[page 2 of 2]
[REDACTED]

A1: appendix
A2: proximal margin
A3: distal margin
A4-7: sections of tumor
A8-12: sections of cecal polypoid mass in the area of the appendiceal orifice
A13: uninvolved colon proximal to the tumor
A14: uninvolved colon distal to the tumor
A15-16: lymph node underlying the tumor
A17-18: lymph node from the ileocecal artery region
Tissue procurement was performed on the specimen. Gross photographs are taken of the specimen.

[REDACTED]

Source: NCI Genomic Data Commons file 1fed5ea3-659b-4151-b053-424471b13bfa (TCGA-G4-6626.CDE2661B-5CFE-4295-A585-75DAACB1B9AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).